Somatic mutation profile of tumor specimen TCGA-S7-A7WQ-01A (aliquot TCGA-S7-A7WQ-01A-12D-A35I-08) from TCGA case TCGA-S7-A7WQ, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 19.9 years (7,269 days).
Specimen TCGA-S7-A7WQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) faf8e696-d60b-421b-924a-5332872c4bcc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S7-A7WQ-10A (Blood Derived Normal), aliquot TCGA-S7-A7WQ-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2d97819-9b89-4c6e-804c-e54081e6b3cd

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Splice Region 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF15 | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs747278375, COSV100730045; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAGE1 | c.1264G>T p.E422* (on ENST00000512086; = p.E286* on NM_205864.3) | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV57078153; called by mutect2, varscan2
- FADD | c.350G>C p.R117P | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99042422; called by muse, mutect2, varscan2
- STK40 | c.342G>A p.Q114= | Splice Region (SNP) | VAF 8/29 reads (28%) | catalogued as rs769653507; called by muse, mutect2, varscan2
- ATAD3B | c.781C>A p.L261M (on ENST00000308647; = p.L367M on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FAM107A | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- OR8A1 | c.67C>T p.L23F | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ZNF287 | c.1207A>G p.K403E | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TAF9 | c.393T>G p.S131= | Silent (SNP) | VAF 11/204 reads (5%) | catalogued as rs778451744; called by muse, mutect2
